CCDI case PBBKZT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9b4c9a19-2e8d-415c-805a-8521a7bedf1d

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.5 years (5,678 days).

Biospecimens (3 samples)
- Sample 0DBN9N: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DBNBE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DBNBM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
